Somatic mutation profile of tumor specimen TCGA-06-6700-01A (aliquot TCGA-06-6700-01A-12D-1845-08) from TCGA case TCGA-06-6700, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.2 years (27,850 days).
Specimen TCGA-06-6700-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5164e8bf-589f-40fa-a34e-bc4b80af9ee8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6700-10A (Blood Derived Normal), aliquot TCGA-06-6700-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc8ee3a4-493b-482b-84a1-7ca4d592a4c7

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Nonsense Mutation 3, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MFAP5 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as rs962247688, COSV63945086; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD28 | c.2899G>A p.A967T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV67516937; called by muse, mutect2
- BOD1L1 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50006654; called by muse, mutect2, varscan2
- CD244 | c.270G>C p.L90F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs956658116, COSV59236197; called by muse, mutect2, varscan2
- CD63 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as rs200393279; called by muse, mutect2, varscan2
- CELF4 | c.7A>T p.I3L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.456); catalogued as COSV58446923; called by muse, mutect2, varscan2
- DNAI3 | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.313); catalogued as rs199645222, COSV54000649; called by muse, mutect2, varscan2
- EDC4 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.479); catalogued as COSV59301662; called by muse, mutect2, varscan2
- EP400 | c.5675A>G p.D1892G | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57763245; called by muse, mutect2, varscan2
- EPHA1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51968479; called by muse, mutect2, varscan2
- GABRA5 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV59475991; called by muse, mutect2, varscan2
- GCSAML | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs747408807, COSV63577121, COSV63577142; called by mutect2, varscan2
- GFRAL | c.1050A>T p.G350= | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as COSV61228836; called by muse, mutect2, varscan2
- GRTP1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376648575; called by muse, mutect2, varscan2
- HMCN1 | c.13661G>A p.R4554H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755169660, COSV54878277; called by mutect2, varscan2
- IMPG1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1268243571, COSV64054358; called by muse, mutect2, varscan2
- MARCHF6 | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV56878813; called by muse, mutect2, varscan2
- NCAPG2 | c.2692G>T p.D898Y | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51984761; called by muse, mutect2, varscan2
- NLRP5 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV66762129; called by muse, mutect2, varscan2
- NUP210L | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs745416091, COSV55141814; called by muse, mutect2, varscan2
- OR10A6 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs538357088, COSV59164541; called by muse, mutect2, varscan2
- OR2T12 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs779382803, COSV58776117; called by muse, mutect2, varscan2
- PCCA | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774738181, COSV66188256; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCK1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs574426927, COSV60126205; called by muse, mutect2, varscan2
- PCLO | c.4017A>G p.T1339= | Splice Region (SNP) | VAF 25/116 reads (22%) | catalogued as COSV61616696; called by muse, mutect2, varscan2
- SLC22A3 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51710179; called by muse, mutect2, varscan2
- SLC26A2 | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1448915287, COSV53824348; called by muse, mutect2, varscan2
- SLC3A2 | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV58602847; called by muse, mutect2, varscan2
- SPACA3 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs368023924; called by muse, mutect2, varscan2
- TAGLN2 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV57421609; called by muse, mutect2, varscan2
- TENM3 | c.6703C>T p.R2235C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101305450, COSV69299638; called by muse, mutect2, varscan2
- TGIF2LX | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as rs763760276, COSV52215133, COSV99383481; called by muse, mutect2, varscan2
- TMEM132B | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245684463, COSV54745134; called by muse, mutect2, varscan2
- UGT8 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV60416449; called by muse, mutect2, varscan2
- VARS1 | c.3710A>G p.E1237G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV63304222; called by muse, mutect2, varscan2
- WDR81 | c.3211G>A p.V1071I (on ENST00000409644 / NM_001163809.2; = p.V20I on NM_152348.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.267); catalogued as rs547107402, COSV58485899; called by muse, mutect2, varscan2
- ZBTB17 | c.2243A>G p.Q748R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV65268221; called by muse, mutect2, varscan2
- ZNF619 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.143); catalogued as COSV59029447; called by muse, mutect2, varscan2
- CYP2F1 | c.1134C>T p.R378= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1252256697, COSV58526680; called by muse, mutect2, varscan2
- FTHL17 | c.135C>T p.D45= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV63266352; called by muse, mutect2, varscan2
- IGHV3-11 | c.321C>T p.A107= | Silent (SNP) | VAF 31/209 reads (15%) | called by muse, mutect2, varscan2
- MZT2B | c.438G>A p.G146= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV56058218; called by muse, mutect2, varscan2
- OR5A1 | c.369C>T p.Y123= | Silent (SNP) | VAF 63/258 reads (24%) | catalogued as rs139346783; called by muse, mutect2, varscan2
- OXNAD1 | c.540A>G p.G180= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV53265849; called by muse, mutect2, varscan2
- PCSK6 | c.546G>A p.S182= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1347511017, COSV59338376; called by muse, mutect2, varscan2
- PIK3R5 | c.2355C>T p.N785= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV52650611; called by muse, mutect2
- RBM15B | c.1326G>A p.G442= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV60371127; called by muse, mutect2
- RIOX1 | c.1572C>T p.Y524= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs200159534; called by mutect2, varscan2
- SERPINB4 | c.534C>T p.N178= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs763091506, COSV104417763, COSV61984183; called by muse, mutect2, varscan2
- STX3 | c.807G>T p.V269= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV55695050; called by muse, mutect2
- UNC79 | c.5865C>T p.N1955= (on ENST00000393151 / NM_001346218.2; = p.N1778= on NM_020818.5) | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs745532875, COSV56374402, COSV56394379; called by muse, mutect2
- STARD7-AS1 | n.1455C>T | RNA (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
